Somatic mutation profile of tumor specimen 0DLBMR from CCDI case PBBZCV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.0 years (4,393 days).
Specimen 0DLBMR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15dc3412-e22e-4d97-bdf9-e216e474919b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLBLZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/349c68b3-8385-492a-aab8-ccce89dfb539

The open-access MAF lists 32 somatic variants for this specimen: 19 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 9, 5'UTR 2, 3'UTR 1, Frame Shift Ins 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1E | c.4408C>T p.R1470C | Missense Mutation (SNP) | VAF 171/586 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1328011806, COSV62409697; called by muse, mutect2, varscan2
- COL22A1 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 221/463 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs531298353, COSV100278951; called by muse, varscan2
- KLB | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 121/581 reads (21%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.651); catalogued as COSV57301574; called by muse, mutect2, varscan2
- MMP12 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 123/441 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs180918521; called by muse, mutect2, varscan2
- PKLR | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 14/398 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1216054637; called by muse, mutect2
- RUVBL1 | c.1313A>G p.Y438C | Missense Mutation (SNP) | VAF 145/580 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as rs765055859; called by muse, mutect2, varscan2
- SAFB | c.2174C>T p.P725L | Missense Mutation (SNP) | VAF 128/452 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.321); catalogued as rs770217810; called by muse, mutect2, varscan2
- SETD1A | c.4211C>T p.P1404L | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as rs575800239, COSV99353713; called by muse, mutect2, varscan2
- TCOF1 | c.2515G>A p.V839I (on ENST00000377797 / NM_001135243.1; = p.V762I on NM_000356.4) | Missense Mutation (SNP) | VAF 99/718 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as rs140126499; called by muse, mutect2, varscan2
- TIMP2 | c.630dup p.K211Qfs*44 | Frame Shift Ins (INS) | VAF 121/820 reads (15%) | catalogued as rs1411147300; called by mutect2, pindel, varscan2
- UBE3C | c.2819G>A p.R940H | Missense Mutation (SNP) | VAF 128/1080 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1377423361; called by muse, mutect2, varscan2
- AC006059.2 | c.2172T>G p.S724R | Missense Mutation (SNP) | VAF 57/362 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- ADAMTS20 | c.1273A>G p.T425A | Missense Mutation (SNP) | VAF 85/312 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EFCAB5 | c.1760G>A p.G587E | Missense Mutation (SNP) | VAF 223/1158 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GTF3C1 | c.3275C>T p.A1092V | Missense Mutation (SNP) | VAF 127/479 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PRKG1 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 117/335 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.47182A>G p.T15728A (on ENST00000591111; = p.T8304A on NM_003319.4) | Missense Mutation (SNP) | VAF 65/360 reads (18%) | PolyPhen benign (0.118); called by muse, mutect2, varscan2
- WNT3A | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 25/445 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- ZNF585A | c.962_963del p.T321Kfs*17 (on ENST00000292841 / NM_001288800.2; = p.T266Kfs*17 on NM_152655.3) | Frame Shift Del (DEL) | VAF 114/471 reads (24%) | called by pindel, varscan2
- ATF5 | c.147C>T p.G49= | Silent (SNP) | VAF 14/377 reads (4%) | catalogued as rs1054070695; called by muse, mutect2
- HPS3 | c.270T>G p.A90= | Silent (SNP) | VAF 20/652 reads (3%) | called by muse, mutect2
- MAP3K21 | c.45C>T p.S15= | Silent (SNP) | VAF 83/465 reads (18%) | called by muse, mutect2, varscan2
- MUC12 | c.1239C>G p.T413= (on ENST00000379442; = p.T270= on NM_001164462.1) | Silent (SNP) | VAF 64/763 reads (8%) | called by muse, mutect2
- SELL | c.1107G>A p.R369= (on ENST00000650983; = p.R356= on NM_000655.5) | Silent (SNP) | VAF 47/370 reads (13%) | catalogued as rs761200314; called by muse, mutect2, varscan2
- SPATA31A6 | c.1929G>A p.T643= | Silent (SNP) | VAF 22/769 reads (3%) | catalogued as rs1161714028, COSV60533314; called by muse, mutect2
- UNC80 | c.8880G>T p.S2960= | Silent (SNP) | VAF 122/612 reads (20%) | catalogued as rs564176510; called by muse, mutect2
- ZDHHC18 | c.39C>A p.A13= | Silent (SNP) | VAF 35/293 reads (12%) | called by muse, mutect2, varscan2
- ZNF282 | c.1059C>T p.P353= | Silent (SNP) | VAF 110/710 reads (15%) | catalogued as COSV50479651; called by muse, mutect2, varscan2
- CALHM2 | c.-49G>A | 5'UTR (SNP) | VAF 71/287 reads (25%) | catalogued as rs935008640; called by muse, mutect2, varscan2
- KRT27 | c.*41C>G | 3'UTR (SNP) | VAF 73/336 reads (22%) | catalogued as rs1181587653, COSV100053366; called by muse, mutect2, varscan2
- LFNG | c.-54T>C | 5'UTR (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- PSG7 | c.988+62G>A | Intron (SNP) | VAF 116/198 reads (59%) | catalogued as rs529014255; called by muse, mutect2, varscan2
